Somatic mutation profile of tumor specimen TCGA-KL-8339-01A (aliquot TCGA-KL-8339-01A-11D-2310-10) from TCGA case TCGA-KL-8339, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.2 years (24,545 days).
Specimen TCGA-KL-8339-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c43286a-609f-4692-80c2-f2c20fa3ae54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8339-11A (Solid Tissue Normal), aliquot TCGA-KL-8339-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c256385f-f3be-421b-974e-c75907e3fe67

The open-access MAF lists 41 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 32/36 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as rs1232400804, COSV101434971; called by muse, mutect2
- ANKRD2 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100080871, COSV53969324; called by muse, mutect2, varscan2
- ASB15 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99306582; called by muse, mutect2, varscan2
- CLOCK | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 71/316 reads (22%) | catalogued as COSV100011813; called by muse, mutect2, varscan2
- CMYA5 | c.10699G>A p.V3567I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101484068; called by muse, mutect2, varscan2
- FKBP4 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761447742, COSV99133754; called by muse, mutect2, varscan2
- FSTL4 | c.2344G>T p.A782S | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV99532684; called by muse, mutect2, varscan2
- FUBP3 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs767321671, COSV100156133; called by muse, mutect2, varscan2
- H2BC17 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as rs1178113641, COSV100377604; called by muse, mutect2
- KCTD8 | c.1011A>C p.K337N | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100759594; called by muse, mutect2, varscan2
- KRT1 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 98/353 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV99358794; called by muse, varscan2
- LOX | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99140645; called by muse, mutect2, varscan2
- NECTIN2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs111808500; called by muse, mutect2
- NEUROG1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130801; called by muse, mutect2, varscan2
- NIPSNAP1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53341794, COSV99331156; called by muse, mutect2, varscan2
- OPN4 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV99555265; called by muse, mutect2
- PDZRN4 | c.2886C>A p.F962L (on ENST00000402685 / NM_001164595.2; = p.F704L on NM_013377.4) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.47); catalogued as COSV100114569, COSV54201761; called by muse, mutect2, varscan2
- PNPLA7 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99480778; called by muse, mutect2, varscan2
- PRSS45P | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101373958; called by muse, mutect2, varscan2
- RASAL1 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs149732792; called by muse, mutect2, varscan2
- RNF167 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99337390; called by muse, mutect2, varscan2
- RSKR | c.15C>G p.S5R | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV99972111; called by muse, mutect2, varscan2
- RUFY4 | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100723078; called by muse, mutect2, varscan2
- SCT | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV99449262; called by muse, mutect2, varscan2
- SERPINB8 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54639203; called by muse, mutect2, varscan2
- SLC18B1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749738886, COSV99259105; called by muse, mutect2, varscan2
- SRGN | c.403T>C p.S135P | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99653740; called by muse, mutect2
- VAV3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.789); catalogued as rs139065569; called by muse, mutect2, varscan2
- WDR72 | c.2134G>T p.V712F | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100854526; called by muse, mutect2, varscan2
- MED21 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.187); called by muse, mutect2
- METTL15 | c.291del p.F97Lfs*31 | Frame Shift Del (DEL) | VAF 38/212 reads (18%) | called by mutect2, pindel, varscan2
- ADCY4 | c.2748C>A p.P916= | Silent (SNP) | VAF 34/350 reads (10%) | catalogued as COSV100156597; called by muse, mutect2
- AMIGO3 | c.1191C>T p.L397= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100246536; called by muse, mutect2, varscan2
- COL22A1 | c.3231C>T p.A1077= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as rs368271751; called by muse, mutect2, varscan2
- HES6 | c.588T>C p.A196= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV99800756; called by muse, mutect2, varscan2
- KCNF1 | c.1206C>T p.I402= | Silent (SNP) | VAF 45/51 reads (88%) | catalogued as COSV54465256, COSV99705718; called by muse, mutect2, varscan2
- KCNQ3 | c.2502C>T p.A834= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs1248992112, COSV101196100, COSV66478182; called by muse, mutect2, varscan2
- KIAA0753 | c.1320G>A p.K440= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs768455971, COSV100810603; called by muse, mutect2, varscan2
- PDZRN3 | c.801G>C p.R267= | Silent (SNP) | VAF 63/133 reads (47%) | catalogued as COSV99729831; called by muse, mutect2, varscan2
- SCN10A | c.5028C>A p.P1676= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as COSV101479403; called by muse, mutect2
